Gene-level copy-number profile of tumor specimen TCGA-SG-A849-01A from TCGA case TCGA-SG-A849, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 78.0 years (28,498 days).
Specimen TCGA-SG-A849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.00e80dbf-ab3c-4920-a3bc-9d8225a4030c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SG-A849-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4996d086-40e7-4abd-9411-53e6776cc44f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 4,191; copy number 2: 23,432; copy number 3: 14,326; copy number 4: 11,307; copy number 5: 5,572; copy number 6: 382; copy number 7: 353; copy number 8: 119; copy number 11: 68; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SG-A849-01A-11D-A350-01): tumor purity 0.3, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:24,789,734–24,919,839, 4 genes (within-gene range 0–2): PTRHD1, CENPO, ADCY3, AC012073.1.
- chr9:21,160,235–23,438,700, 55 genes (within-gene range 0–3): Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,499 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,250,139–68,538,627, 412 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:106,544,342–121,580,524, 378 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–12,769,457, 184 genes, copy number 5–7 (broad region; genes not listed).
- chr3:24,687,919–26,347,638, 20 genes, copy number 5 (within-gene range 4–5): AC092422.1, RN7SL216P, RNA5SP125, RARB, CFL1P7, RNA5SP126, H3P10, AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1, OXSM, LINC00692, RPEP2, HMGB3P12, VENTXP4.
- chr4:49,486,926–52,097,299, 20 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18.
- chr4:117,406,166–117,691,188, 1 gene, copy number 5 (within-gene range 3–5): LINC01378.
- chr4:117,574,512–120,564,789, 45 genes, copy number 5–6: NT5C3AP1, AC092661.1, LINC02264, NDST3, FKBP4P1, SNHG8, SNORA24, PRSS12, NDUFS5P5, AC092670.1, CEP170P1, AC110079.1, RNU6-1054P, CICP16, SEPTIN14P4, METTL14-DT, METTL14, SEC24D, SYNPO2, AC096745.1, MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P, AC093752.1, AC093752.2, PDE5A, AC080089.1, AC080089.2, LINC01365, AC097173.1, LINC02502, Y_RNA, AC097173.2, MAD2L1, AC073475.1, LTV1P1, SAR1AP3.
- chr4:121,131,408–122,922,968, 29 genes, copy number 6 (within-gene range 2–6): TNIP3, RNU6-948P, QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6.
- chr5:10,971,836–11,904,446, 1 gene, copy number 5 (within-gene range 3–5): CTNND2.
- chr5:12,297,399–18,236,196, 101 genes, copy number 5 (broad region; genes not listed).
- chr7:182,935–7,104,482, 171 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:48,171,458–62,275,678, 218 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:112,616,440–148,420,998, 696 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:32,927,913–33,045,445, 4 genes, copy number 8 (within-gene range 3–8): AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr8:35,862,123–50,796,692, 263 genes, copy number 5–12 (broad region; genes not listed).
- chr9:14,475–13,034,326, 170 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–123,115,477, 1,052 genes, copy number 5–7 (broad region; genes not listed).
- chr9:123,111,546–123,111,643, 1 gene, copy number 5: MIR600.
- chr10:4,871,901–5,763,740, 33 genes, copy number 6: AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1.
- chr10:5,776,071–5,776,858, 1 gene, copy number 6: NRBF2P5.
- chr14:24,809,656–25,050,297, 1 gene, copy number 6 (within-gene range 4–6): STXBP6.
- chr14:25,124,467–85,654,428, 1,050 genes, copy number 5–6 (broad region; genes not listed).
- chr14:90,061,994–106,875,071, 705 genes, copy number 5–7 (broad region; genes not listed).
- chr15:50,417,385–64,455,303, 294 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:9,910,606–28,196,381, 518 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:894,435–5,989,369, 90 genes, copy number 5–7 (within-gene range 2–11) (broad region; genes not listed).
- chr22:44,606,939–46,113,928, 41 genes, copy number 5 (within-gene range 3–5): LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619.

Autosomal genes at a single copy (total copy number 1): 2,680. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
